Somatic mutation profile of tumor specimen TARGET-10-PANZFN-09A (aliquot TARGET-10-PANZFN-09A-01D) from TARGET case TARGET-10-PANZFN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,276 days).
Specimen TARGET-10-PANZFN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21971840-fc1b-4da7-b9b1-af6091868e52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANZFN-14A (Bone Marrow Normal), aliquot TARGET-10-PANZFN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7eb25e75-0da2-4978-825b-c561c46c592e

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, 3'UTR 2, Frame Shift Ins 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10L | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746824462; called by muse, mutect2, varscan2
- MEFV | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54827760; called by muse, mutect2
- RASD2 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as rs766600291, COSV53352327; called by muse, mutect2, varscan2
- SERPINA4 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs201071840; called by muse, mutect2
- SYNE1 | c.5413C>T p.R1805W (on ENST00000367255 / NM_182961.4; = p.R1812W on NM_033071.3) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs763781396, COSV99561846; called by muse, mutect2, varscan2
- TAOK3 | c.2454G>A p.M818I | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV66827971; called by muse, mutect2, varscan2
- CIITA | c.3012_3013insAGA p.V1004_S1005insR | In Frame Ins (INS) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- DDX59 | c.790_791insCT p.R264Pfs*21 | Frame Shift Ins (INS) | VAF 14/156 reads (9%) | called by mutect2, pindel*
- MTA3 | c.185A>T p.H62L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABO | c.648C>T p.R216= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as rs782406528; called by muse, mutect2, varscan2
- DNAH2 | c.936G>A p.S312= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1442133875, COSV50013187; called by muse, mutect2
- FAM111B | c.1977C>A p.G659= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as rs1393890818; called by muse, mutect2, varscan2
- PKHD1 | c.2982G>T p.R994= | Silent (SNP) | VAF 11/186 reads (6%) | catalogued as COSV100582078; called by muse, mutect2
- SNTB1 | c.1266C>T p.S422= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs1233511204, COSV101180054, COSV101180188; called by muse, mutect2, varscan2
- GHRH | c.*59C>T | 3'UTR (SNP) | VAF 7/178 reads (4%) | catalogued as COSV52902130; called by muse, mutect2
- GHRH | c.*58C>T | 3'UTR (SNP) | VAF 7/180 reads (4%) | called by muse, mutect2
- IGKV4-1 | chr2:88886154 del C | 3'Flank (DEL) | VAF 22/34 reads (65%) | called by mutect2, pindel, varscan2
